CCDI case PBBZXS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/8c6dfe2f-6d8d-4530-8c85-07f082497d94

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Granulosa cell tumor, malignant: ICD-O-3 morphology code: 8620/3; Tissue or organ of origin: Ovary; Age at diagnosis: 17.6 years (6,443 days).

Biospecimens (3 samples)
- Sample 0DLX4P: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLX59: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DLX5K: Tissue type: Tumor; Specimen type: Solid Tissue.
